Somatic mutation profile of tumor specimen TCGA-B2-5633-01A (aliquot TCGA-B2-5633-01A-01D-A270-10) from TCGA case TCGA-B2-5633, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.1 years (20,493 days).
Specimen TCGA-B2-5633-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a22df6d-054d-4dda-939c-7600117e8209.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5633-10A (Blood Derived Normal), aliquot TCGA-B2-5633-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e10f55a-045e-4df8-bd46-ecd0d47d0bdc

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 3, Intron 2, Splice Site 2, Frame Shift Del 1, Nonstop Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAMP | c.121+2T>C p.X41_splice | Splice Site (SNP) | VAF 50/211 reads (24%) | catalogued as COSV99297902; called by muse, mutect2, varscan2
- ACTN4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV53149221; called by muse, mutect2
- ATP13A5 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV60873395; called by muse, mutect2, varscan2
- ATP2A3 | c.2496G>C p.W832C | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99989084; called by muse, mutect2, varscan2
- CENPW | c.188G>C p.C63S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100851374, COSV64177147; called by muse, mutect2, varscan2
- CHFR | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57177121, COSV99905302; called by muse, mutect2, varscan2
- DHX36 | c.1223T>A p.V408D | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57671391, COSV57676035; called by muse, mutect2, varscan2
- DNM3 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs371617456, COSV62464646; called by muse, mutect2, varscan2
- FARP1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV60336606, COSV60344986; called by muse, mutect2, varscan2
- GAP43 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311063650, COSV59347350; called by muse, varscan2
- GLUD2 | c.611G>T p.R204M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100046738; called by muse, mutect2
- GON4L | c.6068T>C p.V2023A | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99674109; called by muse, mutect2, varscan2
- KCNH7 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as COSV59809013; called by muse, mutect2
- KMT2C | c.8887C>T p.R2963C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs187761353, COSV51484732; called by muse, mutect2, varscan2
- LAMA3 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.92); catalogued as COSV58076230; called by muse, mutect2, varscan2
- LARP1 | c.2533A>T p.T845S (on ENST00000518297 / NM_033551.3; = p.T768S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV60430307; called by muse, mutect2, varscan2
- LRWD1 | c.898T>A p.F300I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52961755; called by muse, mutect2, varscan2
- NFAT5 | c.2212T>A p.S738T | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63031099; called by muse, mutect2, varscan2
- NFAT5 | c.2213C>A p.S738* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | catalogued as COSV63031111; called by muse, mutect2, varscan2
- NMUR2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1326243803, COSV54917555, COSV99677224; called by muse, mutect2, varscan2
- OR11G2 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV62132924; called by muse, mutect2
- OR2A4 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs761209612, COSV59576228; called by muse, mutect2, varscan2
- OR52A5 | c.951A>G p.*317Wext*9 | Nonstop Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV56616363; called by muse, mutect2, varscan2
- PACSIN2 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54322324, COSV99606227; called by muse, mutect2, varscan2
- RASSF2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs748168721, COSV65082559; called by muse, mutect2, varscan2
- RBM39 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV53615420; called by muse, varscan2
- ROS1 | c.6922G>C p.E2308Q | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV63855497, COSV63860020; called by muse, mutect2, varscan2
- SEMA3G | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV51597672; called by muse, mutect2, varscan2
- SLC6A17 | c.1760G>T p.S587I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58995704; called by muse, mutect2, varscan2
- SPDL1 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV54669266; called by muse, mutect2, varscan2
- TEAD2 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369344041; called by muse, mutect2, varscan2
- TLR10 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV58301773; called by muse, mutect2, varscan2
- TNS1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV50747126; called by muse, mutect2, varscan2
- TOP1 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63695584; called by muse, mutect2, varscan2
- UBIAD1 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65148118; called by muse, mutect2, varscan2
- WDFY3 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 122/434 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs201745590, COSV55710898; called by muse, mutect2, varscan2
- CDK12 | c.4283_4284insAAA p.S1427_N1428insK (on ENST00000447079 / NM_016507.4; = p.S1418_N1419insK on NM_015083.3) | In Frame Ins (INS) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- IL18RAP | c.1265del p.S422Mfs*7 | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- NRIP1 | c.1893dup p.Q632Tfs*30 | Frame Shift Ins (INS) | VAF 28/125 reads (22%) | called by mutect2, pindel, varscan2
- RHPN2 | c.941_948+14del p.X314_splice | Splice Site (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- FAM114A2 | c.1428C>G p.L476= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV61078538; called by muse, mutect2, varscan2
- FASN | c.5886T>A p.L1962= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100147697; called by muse, mutect2, varscan2
- H4-16 | c.225G>A p.E75= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV63762454; called by muse, mutect2, varscan2
- IARS2 | c.2679C>T p.I893= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as rs113314730, COSV56962955; called by muse, mutect2, varscan2
- IGSF22 | c.1197C>T p.F399= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV60032425, COSV60037419; called by muse, mutect2, varscan2
- NEU3 | c.927A>T p.P309= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs766760875, COSV53638415; called by muse, mutect2, varscan2
- SHROOM4 | c.30C>T p.Y10= | Silent (SNP) | VAF 59/111 reads (53%) | catalogued as COSV56795256; called by muse, mutect2, varscan2
- SLC15A3 | c.1026T>G p.L342= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV50017394; called by muse, mutect2, varscan2
- SLC35D1 | c.846T>G p.A282= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV52432776; called by muse, mutect2, varscan2
- SOBP | c.2559G>C p.G853= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV57999269; called by muse, mutect2, varscan2
- ZC3H7B | c.1548G>A p.R516= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV60964064; called by muse, mutect2, varscan2
- JMJD1C | c.333+7312G>C | Intron (SNP) | VAF 26/95 reads (27%) | catalogued as COSV67866238; called by muse, mutect2, varscan2
- KIF1B | c.2115+7264T>C | Intron (SNP) | VAF 55/231 reads (24%) | catalogued as COSV55813901; called by muse, mutect2, varscan2
